Somatic mutation profile of tumor specimen TCGA-GF-A769-01A (aliquot TCGA-GF-A769-01A-32D-A32N-08) from TCGA case TCGA-GF-A769, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 39.2 years (14,304 days).
Specimen TCGA-GF-A769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f15cc8b-878e-4858-a9a1-7e2d5339661c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GF-A769-10A (Blood Derived Normal), aliquot TCGA-GF-A769-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68dee70f-4de6-4880-9011-8362f88b56e4

The open-access MAF lists 179 somatic variants for this specimen: 110 protein-altering or splice-affecting, 63 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 63, Nonsense Mutation 4, Intron 3, 3'UTR 2, Frame Shift Del 1, 5'Flank 1, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGRN | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs916658038, COSV101039189; called by muse, mutect2, varscan2
- AHCTF1 | c.1243G>T p.V415F (on ENST00000366508; = p.V389F on NM_015446.5) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404618; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 117/135 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANKFY1 | c.3277C>T p.R1093* (on ENST00000341657 / NM_001330063.2; = p.R1094* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 70/113 reads (62%) | catalogued as COSV58914593; called by muse, mutect2, varscan2
- ARHGAP15 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99714563; called by muse, mutect2, varscan2
- CARMIL2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200130634, COSV100576419; called by muse, mutect2, varscan2
- CD33 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99220895; called by muse, mutect2, varscan2
- CEMIP | c.3393G>A p.W1131* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99587473; called by muse, mutect2, varscan2
- CFAP53 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV68351208; called by muse, mutect2, varscan2
- CHRNB2 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.221); catalogued as COSV100872707; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 116/202 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- COL9A1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.848); catalogued as COSV100295919, COSV57888155; called by muse, mutect2, varscan2
- COX10 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.423); catalogued as COSV99886952, COSV99887244; called by muse, mutect2, varscan2
- CSMD2 | c.9470G>A p.R3157H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs753503294, COSV53881918; called by muse, mutect2, varscan2
- CSPG4 | c.3619C>T p.P1207S | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.046); catalogued as COSV100414292; called by muse, mutect2, varscan2
- CYP4F22 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs756447723, COSV54107951; called by muse, mutect2, varscan2
- DCAF6 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs764787359, COSV56578501; called by muse, mutect2, varscan2
- DCAF6 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56584097; called by muse, mutect2, varscan2
- DCANP1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.27); catalogued as COSV72345868; called by muse, mutect2
- DHRS9 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs201781895; called by muse, mutect2, varscan2
- DLGAP4 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV100211409; called by muse, mutect2, varscan2
- DVL3 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99491075; called by muse, mutect2, varscan2
- EGFLAM | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV100380940; called by muse, mutect2, varscan2
- ELOA | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1010162290, COSV69310372; called by muse, mutect2, varscan2
- ERICH3 | c.3434G>A p.G1145E | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV58606891; called by muse, mutect2, varscan2
- ERLIN1 | c.324C>A p.N108K | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV100962357; called by muse, mutect2, varscan2
- FAT3 | c.6835G>A p.D2279N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53182963; called by muse, mutect2, varscan2
- FCRL5 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.366); catalogued as rs1466824364, COSV100709436; called by muse, mutect2, varscan2
- FLT4 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs1377667967, COSV99989531; called by muse, mutect2, varscan2
- GDF5 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 121/209 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385244315, COSV65499959; called by muse, mutect2, varscan2
- GOT1L1 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as COSV100294782; called by muse, mutect2, varscan2
- GPR32 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745443642, COSV99567427; called by muse, mutect2, varscan2
- GRTP1 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1244847281, COSV100391480; called by muse, mutect2, varscan2
- HLA-B | c.699C>A p.Y233* | Nonsense Mutation (SNP) | VAF 74/184 reads (40%) | catalogued as COSV101318296; called by muse, varscan2
- HYDIN | c.10144C>T p.R3382C | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376896772, COSV101158183; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 49/396 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1431535235; called by muse, mutect2
- IGHV4-34 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 266/515 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs776818215; called by muse, mutect2, varscan2
- KRBA1 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.865); catalogued as COSV99753242; called by muse, mutect2
- KRTAP10-8 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555931154, COSV58165797; called by muse, mutect2, varscan2
- LOX | c.1031C>A p.T344K | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99140757; called by muse, mutect2, varscan2
- LRRC55 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs758123914, COSV73006865; called by muse, mutect2, varscan2
- LTBP2 | c.3895G>A p.G1299R | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs914287813, COSV100000832; called by muse, mutect2, varscan2
- MAP4K2 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1445977262, COSV99581943; called by muse, mutect2, varscan2
- MORC2 | c.296A>T p.Q99L (on ENST00000397641 / NM_001303256.3; = p.Q37L on NM_014941.3) | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53196184; called by muse, mutect2, varscan2
- MUC16 | c.36878G>T p.G12293V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101202233; called by muse, mutect2, varscan2
- NCAN | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99387436; called by muse, mutect2, varscan2
- NDST3 | c.1070-1G>A p.X357_splice | Splice Site (SNP) | VAF 31/87 reads (36%) | catalogued as COSV99632187; called by muse, mutect2, varscan2
- NEURL4 | c.4511C>T p.T1504M | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as rs1478264806, COSV100223388; called by muse, mutect2, varscan2
- NF2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 72/106 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100099814; called by muse, mutect2, varscan2
- NTN1 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV99434131; called by muse, varscan2
- OR10H2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.02); catalogued as rs866879265, COSV59946026; called by muse, mutect2, varscan2
- OR4N2 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100269985, COSV60050009; called by muse, mutect2, varscan2
- OR52I1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100331867; called by muse, mutect2, varscan2
- OTOR | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as rs1238562355, COSV55722137; called by muse, mutect2, varscan2
- PARD3B | c.3056C>T p.T1019M (on ENST00000406610 / NM_001302769.2; = p.T950M on NM_057177.7) | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs766162361, COSV62506166; called by muse, mutect2, varscan2
- PCDH15 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 81/96 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229467; called by muse, mutect2, varscan2
- PCLO | c.10109G>A p.S3370N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100439415; called by muse, mutect2, varscan2
- PCSK5 | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs199622036, COSV70449588; called by muse, mutect2, varscan2
- PDE8A | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100052528; called by muse, mutect2, varscan2
- PPP1R3A | c.2930C>T p.S977F | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52893934; called by muse, mutect2, varscan2
- PRAMEF1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180379; called by muse, mutect2, varscan2
- PRKCB | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV57794091; called by muse, mutect2, varscan2
- PRR12 | c.797C>T p.P266L (on ENST00000615927; = p.P1087L on NM_020719.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV101330843; called by muse, mutect2, varscan2
- PSG1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 142/424 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV99741738; called by muse, mutect2, varscan2
- PTPRG | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99877434; called by muse, mutect2, varscan2
- PTPRH | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV99671290; called by muse, mutect2, varscan2
- RASAL2 | c.2577G>T p.L859F | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as COSV100863003; called by muse, mutect2, varscan2
- RBM25 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.081); catalogued as COSV99999222; called by muse, mutect2, varscan2
- RELN | c.7930A>G p.R2644G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100635165; called by muse, mutect2, varscan2
- RELN | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.983); catalogued as COSV100635166; called by muse, mutect2, varscan2
- RHPN1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441369642, COSV100000964; called by muse, mutect2
- RP1 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV99609243; called by muse, mutect2, varscan2
- RPAP1 | c.1749C>T p.V583= | Splice Region (SNP) | VAF 39/101 reads (39%) | catalogued as rs758736569, COSV100427423; called by muse, mutect2, varscan2
- SCARA3 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs374059713, COSV100106898; called by muse, mutect2, varscan2
- SETD1A | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs908339949, COSV99353919; called by muse, mutect2, varscan2
- SH3RF2 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100768103; called by muse, mutect2, varscan2
- SIGLEC12 | c.758G>A p.G253E (on ENST00000291707 / NM_053003.4; = p.G135E on NM_033329.2) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52460753; called by muse, mutect2, varscan2
- SLC16A3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV101125932; called by muse, mutect2
- SLC1A5 | c.665T>A p.V222E | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV101314843; called by muse, mutect2, varscan2
- SLC25A52 | c.914A>C p.K305T (on ENST00000672005; = p.K295T on NM_001034172.4) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99329878; called by muse, mutect2, varscan2
- SMC1B | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663616; called by muse, mutect2, varscan2
- SNW1 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99834573; called by muse, mutect2, varscan2
- SPOCK1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.628); catalogued as COSV99971307; called by muse, mutect2, varscan2
- SQSTM1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs1355548448, COSV100657666, COSV100657733; called by muse, mutect2, varscan2
- SRCAP | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV99351729; called by muse, mutect2, varscan2
- SVOPL | c.970G>A p.G324R (on ENST00000419765; = p.G172R on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs200115398, COSV55990574, COSV99939811; called by muse, mutect2, varscan2
- SYNE1 | c.12284C>T p.S4095F (on ENST00000367255 / NM_182961.4; = p.S4024F on NM_033071.3) | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55121813; called by muse, mutect2, varscan2
- TBC1D14 | c.1346A>G p.N449S | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV101299089; called by muse, mutect2, varscan2
- TDRD5 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV99677510; called by muse, mutect2, varscan2
- TENM4 | c.6325C>T p.R2109C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770521921, COSV53614632; called by muse, mutect2, varscan2
- THEG | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100700679; called by muse, mutect2, varscan2
- TRPC7 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); catalogued as COSV61457421; called by muse, mutect2, varscan2
- TTN | c.83879G>A p.G27960E (on ENST00000591111; = p.G20536E on NM_003319.4) | Missense Mutation (SNP) | VAF 72/113 reads (64%) | PolyPhen possibly damaging (0.536); catalogued as rs773909810, COSV100635635; called by muse, mutect2, varscan2
- TTN | c.43342G>A p.G14448R (on ENST00000591111; = p.G7024R on NM_003319.4) | Missense Mutation (SNP) | VAF 56/241 reads (23%) | PolyPhen probably damaging (0.986); catalogued as COSV100635637; called by muse, mutect2, varscan2
- VIPR2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs773516215, COSV51116512; called by muse, mutect2, varscan2
- WNK2 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99945121; called by muse, mutect2, varscan2
- WWP2 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1477186513, COSV63123969; called by muse, mutect2, varscan2
- YIPF5 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99188504; called by muse, mutect2, varscan2
- ZFHX4 | c.4675C>G p.H1559D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99269145; called by muse, mutect2, varscan2
- ZFHX4 | c.7800A>C p.E2600D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.107); catalogued as COSV99269149; called by muse, mutect2, varscan2
- ZNF780B | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99666303; called by muse, mutect2, varscan2
- ZNF804A | c.2677G>A p.G893S | Missense Mutation (SNP) | VAF 99/175 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100167366, COSV100168082; called by muse, mutect2, varscan2
- ZNF91 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV100323614; called by muse, mutect2, varscan2
- ZNF98 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs1291942791, COSV100757654, COSV63333998; called by mutect2, varscan2
- ZNF99 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as rs779335692, COSV101233847, COSV101233989; called by muse, mutect2, varscan2
- ZSCAN5A | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54226565; called by muse, mutect2, varscan2
- MAP4K5 | c.1573_1581del p.I525_F527del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- RORC | c.1441del p.E481Kfs*115 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1524G>T p.W508C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM10 | c.1539A>G p.A513= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs983276222, COSV99546927; called by muse, mutect2, varscan2
- ADRA1B | c.543C>T p.L181= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV60701922, COSV60703681; called by muse, mutect2, varscan2
- ALG11 | c.468C>T p.S156= | Silent (SNP) | VAF 67/172 reads (39%) | catalogued as COSV101584412; called by muse, mutect2, varscan2
- ALPK3 | c.336G>A p.K112= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99362172; called by muse, mutect2, varscan2
- ARHGEF17 | c.5250C>T p.V1750= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV99737203; called by muse, mutect2, varscan2
- ATP1A2 | c.2025C>T p.L675= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as rs1185155908, COSV63404684; called by muse, mutect2, varscan2
- BCAS1 | c.1533G>A p.K511= | Silent (SNP) | VAF 95/207 reads (46%) | catalogued as COSV101006529; called by muse, mutect2, varscan2
- CACNA1I | c.2412C>T p.F804= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs188852868, COSV100359656; called by muse, varscan2
- COL6A1 | c.2874C>A p.A958= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100720535; called by muse, mutect2, varscan2
- DACT1 | c.1422C>T p.S474= | Silent (SNP) | VAF 153/241 reads (63%) | catalogued as COSV100242184; called by muse, mutect2
- DLGAP2 | c.867C>T p.P289= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as rs533410863, COSV70104741; called by muse, mutect2, varscan2
- DMXL2 | c.6462C>T p.L2154= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV99198970; called by muse, mutect2, varscan2
- DNAAF4 | c.1224G>A p.K408= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100336979; called by muse, mutect2, varscan2
- GARRE1 | c.831C>T p.I277= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs770457248, COSV55103546; called by muse, mutect2, varscan2
- GRM8 | c.1425G>A p.Q475= | Silent (SNP) | VAF 101/114 reads (89%) | catalogued as COSV100286886; called by muse, mutect2, varscan2
- HSPG2 | c.3816C>T p.P1272= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV65972235; called by muse, mutect2, varscan2
- INSRR | c.258C>T p.F86= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs771118104, COSV100948247; called by muse, mutect2, varscan2
- KASH5 | c.1524C>T p.L508= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV101483530; called by muse, mutect2, varscan2
- KCNH1 | c.1635C>T p.S545= (on ENST00000271751 / NM_172362.3; = p.S518= on NM_002238.4) | Silent (SNP) | VAF 58/233 reads (25%) | catalogued as COSV55082527; called by muse, mutect2, varscan2
- KCNH2 | c.1197C>T p.T399= | Silent (SNP) | VAF 115/205 reads (56%) | catalogued as COSV100061447; called by muse, mutect2, varscan2
- KCNH5 | c.1413C>T p.F471= | Silent (SNP) | VAF 81/141 reads (57%) | catalogued as COSV59769482; called by muse, mutect2, varscan2
- KCNIP3 | c.387C>T p.T129= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as rs138182369, COSV54666886; called by muse, mutect2, varscan2
- KIF2B | c.288C>T p.S96= | Silent (SNP) | VAF 312/458 reads (68%) | catalogued as COSV99276506; called by muse, mutect2, varscan2
- KLHDC8A | c.81G>A p.L27= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs1409590280, COSV100903889; called by muse, mutect2, varscan2
- KMT2E | c.1443C>T p.I481= | Silent (SNP) | VAF 92/286 reads (32%) | catalogued as COSV57576615, COSV99997203; called by muse, mutect2, varscan2
- MUC5B | c.13221C>T p.P4407= | Silent (SNP) | VAF 116/215 reads (54%) | catalogued as rs200215946; called by muse, mutect2, varscan2
- NCK1 | c.556C>T p.L186= | Silent (SNP) | VAF 176/209 reads (84%) | catalogued as COSV56640209; called by muse, mutect2, varscan2
- NOX4 | c.729C>T p.F243= | Silent (SNP) | VAF 85/184 reads (46%) | catalogued as COSV54450416; called by muse, mutect2, varscan2
- NRDC | c.1522C>T p.L508= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs139339992; called by muse, mutect2, varscan2
- OR10G9 | c.427C>T p.L143= | Silent (SNP) | VAF 77/172 reads (45%) | catalogued as COSV100901811; called by muse, mutect2, varscan2
- OR4D2 | c.795C>T p.F265= | Silent (SNP) | VAF 222/308 reads (72%) | catalogued as COSV101613831, COSV101613872; called by muse, mutect2, varscan2
- OR51L1 | c.142C>T p.L48= | Silent (SNP) | VAF 63/201 reads (31%) | catalogued as COSV100386516; called by muse, mutect2, varscan2
- OR5M3 | c.774C>T p.L258= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs987404815, COSV100392367, COSV56568116; called by muse, mutect2, varscan2
- PCDH15 | c.1413G>A p.R471= | Silent (SNP) | VAF 82/97 reads (85%) | catalogued as COSV57292425; called by muse, mutect2, varscan2
- PCDHB7 | c.1471C>T p.L491= | Silent (SNP) | VAF 89/236 reads (38%) | catalogued as rs782630090, COSV99177602; called by muse, mutect2, varscan2
- PCDHGB1 | c.2181C>T p.L727= | Silent (SNP) | VAF 73/183 reads (40%) | catalogued as COSV99549425; called by muse, mutect2, varscan2
- PHACTR4 | c.1908C>T p.L636= (on ENST00000373839 / NM_001350159.2; = p.L646= on NM_023923.4) | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as rs1205812464, COSV65783232; called by muse, mutect2, varscan2
- PIK3C2G | c.846C>G p.L282= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99854469; called by muse, mutect2, varscan2
- PLEC | c.12228C>T p.F4076= (on ENST00000322810 / NM_201380.4; = p.F3966= on NM_000445.5) | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs782492397, COSV100514692, COSV100520012; called by muse, mutect2, varscan2
- PPP2R5B | c.426G>A p.P142= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs139405284; called by muse, mutect2, varscan2
- PRTG | c.2010C>T p.T670= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV101221535; called by muse, mutect2, varscan2
- PTPRU | c.2175G>A p.R725= | Silent (SNP) | VAF 91/215 reads (42%) | catalogued as COSV60536694; called by muse, mutect2, varscan2
- SCN1A | c.1188G>A p.G396= | Silent (SNP) | VAF 51/212 reads (24%) | catalogued as rs267598970, COSV57685406; called by muse, mutect2, varscan2
- SIN3B | c.1032C>T p.L344= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV99932179; called by muse, mutect2, varscan2
- SMARCC2 | c.1110C>T p.A370= | Silent (SNP) | VAF 70/90 reads (78%) | catalogued as COSV99912130; called by muse, mutect2, varscan2
- SOGA1 | c.3069C>T p.L1023= | Silent (SNP) | VAF 73/125 reads (58%) | catalogued as COSV99416007; called by muse, varscan2
- SORCS3 | c.3426G>A p.L1142= | Silent (SNP) | VAF 40/50 reads (80%) | catalogued as COSV100865739; called by muse, mutect2, varscan2
- SPANXD | c.171G>A p.R57= | Silent (SNP) | VAF 150/340 reads (44%) | catalogued as rs782110522, COSV65152452; called by mutect2, varscan2
- SPEF2 | c.4020G>A p.R1340= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs1000841244, COSV61548425; called by muse, mutect2, varscan2
- SRGAP3 | c.798C>T p.I266= | Silent (SNP) | VAF 91/107 reads (85%) | catalogued as rs754715058, COSV100841529; ClinVar: likely benign; called by muse, mutect2, varscan2
- STOX2 | c.1468A>C p.R490= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100409340; called by muse, mutect2, varscan2
- SULT1E1 | c.198G>A p.V66= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99895322; called by muse, mutect2, varscan2
- TGM6 | c.2025C>T p.S675= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as COSV52478377; called by muse, mutect2, varscan2
- TJP3 | c.1455G>A p.E485= | Silent (SNP) | VAF 61/135 reads (45%) | catalogued as COSV99516571; called by muse, mutect2, varscan2
- TLR3 | c.1248G>A p.K416= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99711275; called by muse, mutect2, varscan2
- TMEM218 | c.300C>T p.I100= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99692771; called by muse, mutect2, varscan2
- TRAPPC9 | c.240C>T p.L80= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as COSV101228541; called by muse, varscan2
- TRIP11 | c.4194A>T p.L1398= | Silent (SNP) | VAF 106/185 reads (57%) | catalogued as COSV99971315; called by muse, mutect2, varscan2
- TSHZ3 | c.2715C>T p.I905= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV99553169; called by muse, mutect2, varscan2
- TTN | c.17541G>A p.Q5847= (on ENST00000591111; = p.Q4920= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/179 reads (59%) | catalogued as COSV60171724; called by muse, mutect2, varscan2
- UST | c.1131C>T p.F377= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV100820243; called by muse, mutect2, varscan2
- ZNF157 | c.87C>T p.F29= | Silent (SNP) | VAF 66/75 reads (88%) | catalogued as rs758927576, COSV100998458, COSV65658436; called by muse, mutect2, varscan2
- ZNF492 | c.357G>A p.V119= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV101514078; called by muse, mutect2, varscan2
- BIRC5 | c.*10C>T | 3'UTR (SNP) | VAF 59/87 reads (68%) | catalogued as COSV100051515; called by muse, mutect2, varscan2
- ESRRB | c.1296+376C>T | Intron (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99835954; called by muse, mutect2, varscan2
- PTK2 | c.1417+317C>T | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- SLC30A8 | c.*1C>A | 3'UTR (SNP) | VAF 52/129 reads (40%) | catalogued as rs1220746973, COSV101438802; called by muse, mutect2, varscan2
- SUCO | chr1:172532732 G>A | 5'Flank (SNP) | VAF 28/58 reads (48%) | catalogued as COSV55262452, COSV99742333; called by muse, mutect2, varscan2
- TTN | c.10361-4495G>A | Intron (SNP) | VAF 36/96 reads (38%) | catalogued as rs763068739, COSV100635638; called by muse, mutect2, varscan2
